CCG case CUPP-B4ZC — CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d1c837c8-b97a-4695-921f-6cabe5804937

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Switzerland; Year of birth: 1941; Vital status: Dead; Days to death: 686 days (1.9 years); Year of death: 2015; Cause of death: Cancer Related.

Diagnoses (3)
1. Neoplasm, metastatic (the primary disease): ICD-O-3 morphology code: 8000/6; ICD-10 code: C80; Tissue or organ of origin: Unknown primary site; Site of resection or biopsy: Lung, NOS; Classification of tumor: metastasis; Age at diagnosis: 71.7 years (26,183 days); Year of diagnosis: 2013; Method of diagnosis: Biopsy; AJCC staging edition: 7th; AJCC clinical T: T0; AJCC clinical N: N1; AJCC clinical M: M1; AJCC clinical stage: Stage IV; AJCC pathologic T: T0; AJCC pathologic N: N1; AJCC pathologic M: M2; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Bone, NOS / Lung, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 2; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Residual disease: RX; Timepoint category: First Treatment.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS, postoperative; adjuvant Radiation Therapy, NOS, postoperative.
2. Adenocarcinoma, intestinal type: ICD-O-3 morphology code: 8144/3; Tissue or organ of origin: Rectosigmoid junction; Classification of tumor: Prior primary; Age at diagnosis: 65.2 years (23,820 days); Year of diagnosis: 2007; Days to diagnosis: -2,363 days (-6.5 years); AJCC staging edition: 6th; AJCC pathologic T: Tis; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage 0is.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -2,363 days (-6.5 years).
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Progression of the bone (histology not recorded by GDC). Age at diagnosis: 73.0 years (26,659 days); Year of diagnosis: 2014; Days to diagnosis: 476 days (1.3 years).

Follow-up (3 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 80; ECOG performance status: 1.
- Day 476 (progression): Progression or recurrence: Yes; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 476 days (1.3 years).
- Follow-up contacts recording only the day: day 680, day 686.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Anemia / COPD / Epilepsy / Hypertension / Renal Insufficiency.
- Timepoint category: Initial Diagnosis; Weight: 75 kg; Height: 190 cm; BMI: 20.8.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 10; Tobacco smoking onset year: 1960; Tobacco smoking quit year: 1970.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CUPP-B4ZC-NT1-A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B4ZC-NT1-A-1-0-S1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 0.
- Sample CUPP-B4ZC-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B4ZC-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 36; Percent tumor nuclei: 45; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 63; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
